Somatic mutation profile of tumor specimen TCGA-QK-A8ZB-01A (aliquot TCGA-QK-A8ZB-01A-11D-A391-08) from TCGA case TCGA-QK-A8ZB, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 69.0 years (25,192 days).
Specimen TCGA-QK-A8ZB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 730afdb6-f7cc-4271-b331-5b81f769da13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-A8ZB-10A (Blood Derived Normal), aliquot TCGA-QK-A8ZB-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dbdbd4d-82ed-4abf-890a-dc9ea1baef56

The open-access MAF lists 112 somatic variants for this specimen: 79 protein-altering or splice-affecting, 29 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 29, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 3, Intron 2, RNA 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.457+1G>T p.X153_splice | Splice Site (SNP) | VAF 13/40 reads (33%) | hotspot (GDC flag); catalogued as CS041518, CS941435, COSV58685123, COSV58690553, COSV58696311; called by muse, mutect2, varscan2
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 26/65 reads (40%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAA2 | c.216T>A p.H72Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV99551764; called by muse, mutect2, varscan2
- ACTL8 | c.1080T>A p.Y360* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100958558; called by muse, mutect2, varscan2
- ADAMTS16 | c.2292G>A p.M764I | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57006913, COSV99940656; called by muse, mutect2, varscan2
- AGMO | c.150G>C p.L50F | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.046); catalogued as COSV100693904; called by muse, mutect2, varscan2
- ANGPTL5 | c.1049C>G p.S350C | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as COSV100527723; called by muse, mutect2, varscan2
- AP2A1 | c.2656C>G p.Q886E | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs1183052109, COSV100571067; called by muse, mutect2, varscan2
- ASCC3 | c.4751A>G p.D1584G | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV100976332; called by muse, mutect2, varscan2
- CEACAM5 | c.426G>T p.P142= | Splice Region (SNP) | VAF 12/218 reads (6%) | catalogued as rs782357168, COSV99703813; called by muse, mutect2
- CFAP92 | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV99414665; called by muse, mutect2, varscan2
- COL14A1 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.278); catalogued as rs866044345, COSV52856231; called by muse, mutect2
- CSMD3 | c.3445C>G p.L1149V (on ENST00000297405 / NM_001363185.1; = p.L1045V on NM_052900.3) | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs748994731, COSV99829665; called by muse, mutect2, varscan2
- CSMD3 | c.2817-1G>T p.X939_splice (on ENST00000297405 / NM_001363185.1; = p.X835_splice on NM_052900.3) | Splice Site (SNP) | VAF 11/57 reads (19%) | catalogued as COSV52177046; called by muse, mutect2, varscan2
- CSPG4 | c.6750C>G p.N2250K | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.634); catalogued as COSV100413625; called by muse, mutect2, varscan2
- DNAH10 | c.1136C>A p.A379D (on ENST00000409039; = p.A318D on NM_207437.3) | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV101292128; called by muse, mutect2, varscan2
- EPPK1 | c.5485G>A p.E1829K | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.021); catalogued as COSV73261043; called by muse, mutect2
- ERBB3 | c.3583G>A p.E1195K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV99916314; called by muse, mutect2, varscan2
- FAM167A | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.093); catalogued as COSV99461363; called by muse, mutect2, varscan2
- FAT4 | c.13377C>A p.H4459Q | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100627937; called by muse, mutect2, varscan2
- FNIP2 | c.2170T>G p.F724V | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100032377; called by muse, mutect2, varscan2
- GAREM1 | c.1949A>T p.Y650F (on ENST00000269209 / NM_001242409.2; = p.Y649F on NM_022751.3) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); catalogued as COSV99330405; called by muse, mutect2, varscan2
- GIT1 | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs780961355, COSV99838041; called by muse, mutect2, varscan2
- GLP2R | c.1124G>T p.C375F | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV99301787; called by muse, mutect2, varscan2
- GLP2R | c.1468C>T p.L490F | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV99301790; called by muse, mutect2, varscan2
- GPR141 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.829); catalogued as rs375407880; called by muse, mutect2
- GPR50 | c.1705G>T p.A569S | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV54439048, COSV99505868; called by muse, mutect2, varscan2
- HELZ | c.2906A>C p.K969T | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62380034; called by muse, mutect2, varscan2
- IL6ST | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1046072990, COSV100410713; called by muse, mutect2, varscan2
- INPP5F | c.2665C>G p.L889V | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100740055; called by muse, mutect2, varscan2
- KCNC1 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772153533, COSV99788977; called by muse, mutect2, varscan2
- KCNE2 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99285693; called by muse, mutect2, varscan2
- KCNG1 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100857041; called by muse, mutect2, varscan2
- KRT31 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 15/97 reads (15%) | catalogued as COSV99289518; called by muse, mutect2, varscan2
- KRTAP12-4 | c.306A>T p.R102S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV100552547; called by muse, mutect2, varscan2
- LRP1B | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV101254687; called by muse, mutect2, varscan2
- LRRTM3 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63664806; called by muse, mutect2, varscan2
- LSM14B | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1226652675, COSV53381921; called by muse, mutect2, varscan2
- METTL16 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV99563239; called by muse, mutect2, varscan2
- NCAM1 | c.1863G>A p.M621I (on ENST00000316851 / NM_181351.5; = p.M611I on NM_000615.7) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1380523588, COSV100377280; called by muse, mutect2, varscan2
- NEK5 | c.455G>C p.R152T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100839178, COSV62880775; called by muse, mutect2, varscan2
- NFATC2IP | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as COSV100297530; called by muse, mutect2, varscan2
- NODAL | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.272); catalogued as COSV99755396; called by muse, mutect2, varscan2
- NPAS4 | c.48C>G p.I16M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100214891, COSV60648813; called by muse, mutect2, varscan2
- OBSCN | c.4753G>T p.V1585L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.053); catalogued as rs369298350; called by muse, mutect2, varscan2
- PACS1 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1554993480, COSV100269765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH10 | c.2354C>T p.S785L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); catalogued as COSV99993260; called by muse, mutect2, varscan2
- PCDHB6 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.999); catalogued as rs879963699, COSV99169881; called by muse, mutect2, varscan2
- PDE2A | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100557767; called by muse, mutect2, varscan2
- PHF3 | c.3510C>A p.F1170L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100013082; called by muse, mutect2, varscan2
- PILRB | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.908); catalogued as COSV100166977; called by muse, mutect2, varscan2
- PSMD5 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs749755749, COSV99270715; called by muse, mutect2, varscan2
- PTPN6 | c.582C>G p.F194L | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV100017001; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1403A>G p.Y468C | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489145933, COSV100741111; called by muse, mutect2, varscan2
- RBL1 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as rs751432251, COSV100726947; called by muse, mutect2, varscan2
- RNF139 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV99413263; called by muse, mutect2
- RYR2 | c.7905A>C p.E2635D | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV100769037; called by muse, mutect2, varscan2
- SHC4 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100194351; called by muse, mutect2, varscan2
- SHROOM3 | c.5504G>A p.R1835K | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99933918; called by muse, mutect2, varscan2
- SLFN12 | c.458G>C p.R153T | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.161); catalogued as COSV100512982; called by muse, mutect2, varscan2
- SPEN | c.7442C>T p.S2481L | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs997092599, COSV101005089; called by muse, mutect2, varscan2
- SPI1 | c.569G>T p.W190L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99908773; called by muse, mutect2, varscan2
- TAGAP | c.148+1G>T p.X50_splice | Splice Site (SNP) | VAF 47/185 reads (25%) | catalogued as COSV100487341; called by muse, mutect2, varscan2
- TMCC2 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.346); catalogued as COSV100405159; called by muse, mutect2, varscan2
- TTN | c.77405G>A p.R25802H (on ENST00000591111; = p.R18378H on NM_003319.4) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | PolyPhen probably damaging (0.917); catalogued as rs551496477, COSV100602510; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.76580G>A p.R25527H (on ENST00000591111; = p.R18103H on NM_003319.4) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | PolyPhen probably damaging (0.998); catalogued as rs374160272; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UACA | c.3132G>C p.L1044F | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427027182, COSV59854506; called by muse, mutect2, varscan2
- UAP1 | c.408T>G p.F136L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV99617552; called by muse, mutect2
- UNC13C | c.6037G>T p.A2013S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99514203; called by muse, mutect2, varscan2
- USH2A | c.4912A>G p.T1638A | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV100232049; called by muse, mutect2, varscan2
- USP6 | c.3373C>A p.P1125T | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT tolerated, low confidence (0.54); PolyPhen possibly damaging (0.656); catalogued as rs777437418, COSV100003533; called by muse, mutect2, varscan2
- ZFPM2 | c.944T>A p.M315K | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.38); catalogued as COSV101023102, COSV65875036; called by muse, mutect2, varscan2
- ZNF280B | c.79G>C p.D27H | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100840229; called by muse, mutect2, varscan2
- ZNF444 | c.130C>G p.L44V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100442534; called by mutect2, varscan2
- ZNF639 | c.1444C>T p.H482Y | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100418404; called by muse, mutect2, varscan2
- B9D2 | c.58_73del p.S20Gfs*27 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel
- CHUK | c.1132_1167del p.G378_K389del | In Frame Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- KMT2D | c.15184_15202del p.C5062Rfs*10 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- NFE2L1 | c.1588_1595del p.S530Pfs*15 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- ABCG4 | c.1158C>T p.L386= | Silent (SNP) | VAF 74/245 reads (30%) | catalogued as COSV56641779, COSV56643509; called by muse, mutect2, varscan2
- AHNAK | c.10071T>C p.F3357= | Silent (SNP) | VAF 6/115 reads (5%) | catalogued as COSV99946502; called by muse, mutect2
- ALDH16A1 | c.555G>A p.R185= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs768840117, COSV99512731; called by muse, mutect2, varscan2
- ALOX15 | c.1896C>T p.A632= | Silent (SNP) | VAF 40/175 reads (23%) | catalogued as rs181689632, COSV99541280; called by muse, mutect2, varscan2
- BCL9L | c.2427C>T p.P809= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99418958; called by muse, mutect2, varscan2
- FGFR2 | c.1065A>G p.A355= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs1219679394, COSV100335770; called by muse, mutect2
- FXYD1 | c.141C>G p.L47= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99544774; called by muse, mutect2, varscan2
- GIT1 | c.918G>T p.V306= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as COSV99838042; called by muse, mutect2, varscan2
- GRIN2B | c.4242G>A p.A1414= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs202227485, COSV74206756; called by muse, mutect2
- HEATR1 | c.6042G>A p.E2014= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV100857565; called by muse, mutect2, varscan2
- HIVEP2 | c.369G>T p.P123= | Silent (SNP) | VAF 32/123 reads (26%) | catalogued as COSV99171727; called by muse, mutect2, varscan2
- HMBS | c.984G>A p.Q328= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV99597875; called by muse, mutect2, varscan2
- IGHE | c.936G>A p.R312= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1281936441; called by muse, mutect2, varscan2
- KRT14 | c.780G>C p.L260= | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as COSV51420915; called by muse, mutect2
- MGRN1 | c.951G>A p.R317= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV99273926; called by muse, mutect2, varscan2
- MUC2 | c.888C>A p.V296= | Silent (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- NLRP7 | c.1575C>T p.L525= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs1327980893, COSV60182405; called by muse, mutect2, varscan2
- OR10G9 | c.457C>T p.L153= | Silent (SNP) | VAF 29/160 reads (18%) | catalogued as COSV100901531, COSV66686216; called by muse, mutect2, varscan2
- PCDHB13 | c.2010C>T p.Y670= | Silent (SNP) | VAF 47/130 reads (36%) | catalogued as COSV99507024; called by muse, mutect2, varscan2
- PRSS35 | c.447G>A p.K149= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV100864064; called by muse, mutect2, varscan2
- RBPMS | c.477G>A p.A159= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs146741990; called by muse, mutect2, varscan2
- RECQL | c.1629G>A p.E543= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV99556429; called by muse, mutect2, varscan2
- SORL1 | c.2175G>A p.T725= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs774416406, COSV99493301; called by muse, mutect2, varscan2
- TSPAN1 | c.534C>T p.N178= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as rs771685287, COSV100915478; called by muse, mutect2, varscan2
- UBQLNL | c.552T>A p.L184= | Silent (SNP) | VAF 46/186 reads (25%) | catalogued as COSV100974151; called by muse, mutect2, varscan2
- VCAN | c.7059G>A p.T2353= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs148008263; called by mutect2, varscan2
- VPS45 | c.474A>T p.T158= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV100964877; called by muse, mutect2, varscan2
- ZFP28 | c.159C>T p.L53= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs769215555, COSV56737657; called by muse, varscan2
- ZNF224 | c.1872C>G p.L624= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs1053065024, COSV100425342; called by muse, mutect2, varscan2
- BTN2A3P | n.360C>G | RNA (SNP) | VAF 15/71 reads (21%) | called by muse, mutect2, varscan2
- DST-AS1 | n.139+7492T>C | Intron (SNP) | VAF 10/34 reads (29%) | catalogued as COSV66109399; called by muse, mutect2, varscan2
- EPHA8 | c.1315+28G>A | Intron (SNP) | VAF 11/56 reads (20%) | catalogued as rs762667401, COSV51282072; called by muse, mutect2, varscan2
- FAM169B | n.381A>T | RNA (SNP) | VAF 20/100 reads (20%) | catalogued as COSV100259718; called by muse, mutect2, varscan2
